Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A0TW, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A0TW-01A (Primary Tumor).

1CD-0-3

carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9

Breast, right, modified radical mastectomy: Multifocal ductal carcinoma of the breast. The largest tumor is a Nottingham grade III (of III) ductal adenocarcinoma (5.5 cm in greatest dimension). There are multiple (3) additional tumors (all Nottingham grade II (of III) 2.0 cm 1.5 cm, and 1.0 cm in greatest dimension. The surgical margins are negative. Metastatic adenocarcinoma is identified in multiple (3 of 27) right axillary lymph nodes. The largest node of metastasis measures 3.5 cm in greatest dimension. No definite extracapsular extension is identified.

Breast, left, simple mastectomy: Nonproliferative fibrocystic changes characterized by dense fibrosis, cyst formation, and fibroadenomatous change.

Nipples, left and right, excision: Negative for malignancy.

Diagnostic Discrepancy		X

Source: NCI Genomic Data Commons file 09ca0693-cd18-4e3a-9050-b0d8c68dda39 (TCGA-AR-A0TW.F832C787-3668-475F-8F67-6342DA3777F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).